Somatic mutation profile of tumor specimen TARGET-50-PAKYLT-01A (aliquot TARGET-50-PAKYLT-01A-01D) from TARGET case TARGET-50-PAKYLT, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: female; Vital status: Alive; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 6.3 years (2,307 days).
Specimen TARGET-50-PAKYLT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41cd3de6-562f-4e92-a2b0-536056780517.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PAKYLT-10A (Blood Derived Normal), aliquot TARGET-50-PAKYLT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1e08d0a-5c0e-4964-acba-423e1a7d36fd

The open-access MAF lists 29 somatic variants for this specimen: 20 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 8, Intron 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARSJ | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 88/132 reads (67%) | SIFT tolerated (0.15); PolyPhen benign (0.13); catalogued as COSV59538315; called by muse, mutect2, varscan2
- HK2 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.93); PolyPhen benign (0.263); catalogued as rs1284991514, COSV99309510; called by muse, mutect2, varscan2
- OR5L1 | c.121G>C p.A41P | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV61735211; called by muse, mutect2
- PCDHA3 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.927); catalogued as COSV63542874; called by muse, mutect2, varscan2
- TDRD5 | c.1579C>G p.Q527E | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as COSV54251569; called by muse, mutect2
- TOGARAM2 | c.1918G>T p.G640C | Missense Mutation (SNP) | VAF 131/246 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65421056; called by muse, mutect2, varscan2
- ADAMTS10 | c.182C>G p.P61R | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- CCDC125 | c.1319A>G p.N440S | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC171 | c.3539T>A p.L1180Q | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- KRT7 | c.307G>C p.A103P | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by mutect2, varscan2
- MRPS28 | c.421C>G p.R141G | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NCK1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 13/156 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- NXPH3 | c.241C>A p.Q81K | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- NXPH4 | c.748_771del p.L250_C257del | In Frame Del (DEL) | VAF 13/71 reads (18%) | called by mutect2, pindel, varscan2
- PIKFYVE | c.4111T>A p.F1371I | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TNFAIP3 | c.1801A>G p.R601G | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.039); called by muse, mutect2
- TP53 | c.583_584del p.I195Pfs*13 | Frame Shift Del (DEL) | VAF 98/133 reads (74%) | called by mutect2, pindel, varscan2
- TTC27 | c.653A>C p.Q218P | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZKSCAN3 | c.578G>C p.G193A | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.196); called by muse, mutect2
- ZMYM4 | c.4098G>C p.W1366C | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- CCDC7 | c.3546T>C p.D1182= | Silent (SNP) | VAF 87/508 reads (17%) | called by muse, mutect2, varscan2
- CCDC88C | c.1023C>T p.D341= | Silent (SNP) | VAF 13/14 reads (93%) | catalogued as rs762008822, COSV66233537; called by muse, mutect2, varscan2
- FLYWCH1 | c.1587G>A p.E529= (on ENST00000253928 / NM_001308068.2; = p.E528= on NM_020912.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/57 reads (26%) | called by muse, mutect2, varscan2
- GOLGB1 | c.7776C>G p.A2592= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as rs925953569; called by muse, mutect2, varscan2
- JAK2 | c.828A>G p.G276= | Silent (SNP) | VAF 55/408 reads (13%) | catalogued as COSV67678401; called by muse, mutect2, varscan2
- NBAS | c.4188A>C p.V1396= | Silent (SNP) | VAF 26/178 reads (15%) | called by muse, mutect2, varscan2
- USP53 | c.2664A>G p.Q888= | Silent (SNP) | VAF 19/187 reads (10%) | catalogued as rs577899008; called by muse, mutect2, varscan2
- ZHX2 | c.2109C>T p.H703= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as rs375035673; called by muse, mutect2, varscan2
- CCSER1 | c.2011-35266G>T | Intron (SNP) | VAF 12/87 reads (14%) | catalogued as COSV100389835; called by muse, mutect2, varscan2
